Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8058, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8058-01A (Primary Tumor).

[page 1 of 2]
					STOMACH TISSUE CHECKLIST Specimen type: Subtotal gastrectomy Tumor site: Stomach Tumor size: 5 x 4 x 2.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - lesser and greater omentums Lymph nodes: 3/8 positive for metastasis (Intraabdominal 3/8) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None	Antrum	
---	--	--	--	--	--	--------	---

Source: NCI Genomic Data Commons file 4d920359-9ad3-4ff0-9eb4-f15d4f4ec3df (TCGA-BR-8058.F1D91247-04F9-4AA5-A7ED-D1347B837E5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).